Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2M8, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2M8-06A (Metastatic).

PathNet History Upload External
Client

DOB/Age/Sex: Female
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

ARCHIVAL HISTOPATHOLOGY REPORT

Accession Number:

Collected Date:

HISTORICAL REQUEST DETAILS

(R) groin metastatic melanoma

100-0-3

Melanoma, NOS 8720/3

Site: lymph node, inguinal

C77.4

SPECIMEN INFORMATION

Excision multiple nodes (R) groin - ?melanoma. Frozen section + histology.

MACROSCOPIC DESCRIPTION

"Recurrent melanoma right inner thigh". An ellipse of skin, 115 x 24 x 15mm containing several hard lymph nodes. Portion of some of the nodes were taken by Six circles have been previously marked on the skin with a blue felt pen. Three of these circles are overlying enlarged firm lymph node, however the middle three overlie an elongated cord of firm white tissue, 6mm in diameter and 55mm in length. This cord is continuous with enlarged lymph nodes at either end. It may represent tumour in a lymphatic channel.

A&B. Enlarged node at one end of specimen.

C&D. Cord of tissue in eight transverse sections.

E. Large lymph node at proximal end of specimen.

F&G. Large node adjacent to block E.

MICROSCOPIC REPORT

"Recurrent melanoma right inner thigh". All four enlarged lymph nodes show metastatic amelanotic epithelioid cell malignant melanoma with extranodal extension.

Electronic signature

SUMMARY / KEY WORDS

Lymph node, inguinal - malignant melanoma, metastatic
Haematopathology resection

Source: NCI Genomic Data Commons file 96e5d29a-43af-4ca3-abb4-eefb04c6b7d1 (TCGA-EE-A2M8.37DF4914-EC1C-4DDC-BEA5-F5887856BB38.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).